Somatic mutation profile of tumor specimen TCGA-B6-A0RS-01A (aliquot TCGA-B6-A0RS-01A-11D-A099-09) from TCGA case TCGA-B6-A0RS, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 38.7 years (14,134 days).
Specimen TCGA-B6-A0RS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0cf18cbf-f63c-4582-98e4-ce29be2818a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0RS-10A (Blood Derived Normal), aliquot TCGA-B6-A0RS-10A-01W-A097-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f84f8bdf-85e3-44d6-9e94-ef4ae245e6e4

The open-access MAF lists 157 somatic variants for this specimen: 119 protein-altering or splice-affecting, 35 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 108, Silent 35, Splice Site 4, Frame Shift Del 3, In Frame Del 2, Nonsense Mutation 2, 5'UTR 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 35/90 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1272C>A p.D424E (on ENST00000373993 / NM_138932.2; = p.D416E on NM_014576.4) | Missense Mutation (SNP) | VAF 72/186 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.028); catalogued as COSV99255411; called by muse, mutect2, varscan2
- AKNA | c.1794C>G p.F598L | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.12); catalogued as rs755632366, COSV99799828; called by muse, mutect2, varscan2
- ATF2 | c.76C>G p.L26V | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751165068, COSV99908448; called by muse, mutect2, varscan2
- ATP2A3 | c.2984G>C p.C995S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as COSV99988882; called by muse, mutect2
- ATP6V0A4 | c.838C>G p.H280D | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV100022766; called by muse, mutect2, varscan2
- ATP9A | c.760A>T p.I254L | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.044); catalogued as COSV100124462; called by muse, mutect2, varscan2
- BUD23 | c.271G>T p.A91S | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99736351; called by muse, mutect2, varscan2
- C2orf73 | c.139G>C p.G47R | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.027); catalogued as rs763154998, COSV100471243; called by muse, mutect2, varscan2
- CCDC185 | c.705G>A p.M235I | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100838760; called by muse, mutect2, varscan2
- CDH18 | c.2002A>C p.T668P | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99932644; called by muse, mutect2
- CFAP47 | c.29T>A p.I10K | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.277); catalogued as COSV99934549; called by muse, mutect2
- CHD4 | c.888C>G p.I296M | Missense Mutation (SNP) | VAF 46/291 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1314696153, COSV100537512, COSV58909869; called by muse, mutect2, varscan2
- CKAP5 | c.4459G>T p.D1487Y | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100370510; called by muse, mutect2, varscan2
- CMYA5 | c.936G>T p.E312D | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV101483926; called by muse, mutect2, varscan2
- CPZ | c.1127C>T p.S376L (on ENST00000360986 / NM_001014447.3; = p.S365L on NM_003652.3) | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100248651; called by muse, mutect2, varscan2
- DDX59 | c.1483G>C p.D495H | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV100494414; called by muse, mutect2
- DENND2D | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.44); catalogued as rs774863479; called by muse, mutect2, varscan2
- DSP | c.8198C>A p.T2733K | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100672894; called by muse, mutect2, varscan2
- DTX4 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs770339821, COSV99915093; called by muse, mutect2, varscan2
- ENDOU | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 64/198 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99968213; called by muse, mutect2, varscan2
- F5 | c.1763-1G>A p.X588_splice | Splice Site (SNP) | VAF 24/114 reads (21%) | catalogued as COSV100888965; called by muse, mutect2, varscan2
- FAM234B | c.1082A>T p.E361V | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV99545462; called by muse, mutect2
- FFAR3 | c.18C>G p.D6E | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV100588140; called by mutect2, varscan2
- GATM | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 54/94 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101188136; called by muse, mutect2, varscan2
- GRAMD1B | c.1529G>T p.G510V | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100454374, COSV59204602, COSV59205425; called by muse, mutect2
- GRP | c.163A>G p.T55A | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.401); catalogued as rs375754489, COSV56880445; called by muse, mutect2, varscan2
- GSTK1 | c.277G>C p.E93Q | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV64424647; called by muse, mutect2, varscan2
- HSPA1B | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.251); catalogued as rs199562339; called by muse, mutect2, varscan2
- HTATSF1 | c.2002G>T p.A668S | Missense Mutation (SNP) | VAF 36/432 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.058); catalogued as COSV99511435; called by muse, mutect2
- IFIT5 | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100877924; called by muse, mutect2, varscan2
- IL2 | c.239A>G p.E80G | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV99900730; called by muse, mutect2, varscan2
- INPP5D | c.1606G>A p.G536R (on ENST00000445964 / NM_001017915.3; = p.G535R on NM_005541.5) | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100856548; called by muse, mutect2, varscan2
- IRS1 | c.138C>G p.Y46* | Nonsense Mutation (SNP) | VAF 3/25 reads (12%) | catalogued as COSV100524124; called by muse, mutect2
- ITGB1BP2 | c.425T>A p.L142Q | Missense Mutation (SNP) | VAF 49/268 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV99338637; called by muse, mutect2, varscan2
- JMJD1C | c.4813G>T p.D1605Y | Missense Mutation (SNP) | VAF 46/197 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100550202; called by muse, mutect2, varscan2
- KCNT2 | c.2288A>G p.H763R | Missense Mutation (SNP) | VAF 35/265 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV99652017; called by muse, mutect2, varscan2
- KIAA1109 | c.3088G>A p.V1030I | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); catalogued as COSV99146581; called by muse, mutect2, varscan2
- KLF11 | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 17/213 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as COSV100007669; called by muse, mutect2
- LRFN5 | c.348T>G p.N116K | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.21); catalogued as COSV99982780; called by muse, mutect2, varscan2
- LRP2 | c.12524A>C p.Y4175S | Missense Mutation (SNP) | VAF 59/145 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99786869; called by muse, mutect2, varscan2
- LTN1 | c.2687T>G p.L896R | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100797895; called by muse, mutect2
- MAST2 | c.4318G>A p.E1440K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); catalogued as COSV100787922; called by muse, varscan2
- MED12 | c.5896C>G p.P1966A | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as COSV100376551; called by muse, mutect2
- MEI1 | c.2063G>A p.R688H | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as rs779589520, COSV100299687; called by muse, mutect2, varscan2
- METTL4 | c.646C>T p.H216Y | Missense Mutation (SNP) | VAF 41/69 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV100170495; called by muse, mutect2, varscan2
- MOK | c.715T>A p.F239I | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99512946; called by muse, mutect2, varscan2
- MUC16 | c.38539C>A p.P12847T | Missense Mutation (SNP) | VAF 46/207 reads (22%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.251); catalogued as COSV101198492; called by muse, mutect2, varscan2
- MUC16 | c.30763G>C p.V10255L | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.824); catalogued as COSV101198494; called by muse, varscan2
- MUC16 | c.6511A>T p.T2171S | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV101198496; called by muse, mutect2, varscan2
- MUTYH | c.921G>C p.Q307H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs1064793522, COSV100587950; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYLK | c.2053G>T p.V685L | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100658608; called by muse, mutect2, varscan2
- NCAN | c.2650G>C p.V884L | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.054); catalogued as COSV99386697; called by muse, mutect2, varscan2
- NEK10 | c.1439C>G p.A480G | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV100411476; called by muse, mutect2, varscan2
- NLGN4X | c.305A>C p.N102T | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99320276; called by muse, mutect2
- NOL12 | c.397A>T p.R133W | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV100767129; called by muse, mutect2, varscan2
- OPA1 | c.201C>G p.N67K | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0.013); catalogued as COSV100655191; called by muse, mutect2
- OR2S2 | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as COSV100558495; called by muse, mutect2
- OR2T5 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 97/287 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.045); catalogued as rs1191710899, COSV63540626; called by muse, mutect2, varscan2
- OR5M1 | c.450G>T p.M150I | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV101591537, COSV73202454; called by muse, mutect2, varscan2
- OSMR | c.523A>G p.N175D | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV99952753; called by muse, mutect2
- PCDH1 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs201168116, COSV99745622; called by muse, mutect2, varscan2
- PDE5A | c.1073T>C p.I358T | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.019); catalogued as COSV53350383; called by muse, mutect2
- PLPP2 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99514500; called by muse, mutect2, varscan2
- PPP1R32 | c.386G>C p.R129P | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV100087686, COSV100087772, COSV58544996; called by muse, mutect2, varscan2
- PPP1R9A | c.916T>C p.S306P | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99194743; called by muse, mutect2, varscan2
- PRKCQ | c.699A>T p.R233S | Missense Mutation (SNP) | VAF 80/271 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99576441; called by muse, mutect2, varscan2
- PSMD6 | c.583A>C p.K195Q | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99895895; called by muse, mutect2, varscan2
- PTPN3 | c.2488T>C p.S830P | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV99355461; called by muse, mutect2
- RAI14 | c.1597A>C p.N533H | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV99462152; called by muse, mutect2, varscan2
- RGL1 | c.223G>C p.E75Q (on ENST00000360851 / NM_001297672.2; = p.E110Q on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/328 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV58996191; called by muse, mutect2
- RNASE8 | c.460G>T p.V154F | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs1449598800, COSV100373485; called by muse, mutect2, varscan2
- SEMG1 | c.212T>C p.V71A | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as rs1484100099, COSV99725100; called by muse, mutect2, varscan2
- SIGLEC12 | c.1174C>G p.L392V (on ENST00000291707 / NM_053003.4; = p.L274V on NM_033329.2) | Missense Mutation (SNP) | VAF 56/84 reads (67%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.823); catalogued as COSV99389126; called by muse, mutect2, varscan2
- SLC17A7 | c.637+1G>A p.X213_splice | Splice Site (SNP) | VAF 36/137 reads (26%) | catalogued as COSV99676724; called by muse, mutect2, varscan2
- SLC25A15 | c.718C>T p.L240F | Missense Mutation (SNP) | VAF 20/307 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.021); catalogued as COSV100090758; called by muse, mutect2
- SLC35A4 | c.370G>C p.G124R | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV100021193; called by muse, mutect2, varscan2
- SLC35C1 | c.546G>T p.W182C | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV100029344; called by muse, mutect2, varscan2
- SLC36A3 | c.1400G>T p.G467V | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100077406; called by muse, mutect2, varscan2
- SLC9A8 | c.1073G>C p.C358S | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as COSV100846236; called by muse, mutect2, varscan2
- SLCO4A1 | c.1184A>T p.E395V | Missense Mutation (SNP) | VAF 67/150 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV53892574; called by muse, mutect2, varscan2
- SPA17 | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57031905, COSV99906997; called by muse, mutect2, varscan2
- SRCAP | c.6937G>A p.E2313K | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99349489; called by muse, mutect2, varscan2
- TAF9B | c.644G>C p.G215A | Missense Mutation (SNP) | VAF 11/268 reads (4%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.992); catalogued as COSV100540573; called by muse, mutect2
- TAS2R3 | c.802A>C p.I268L | Missense Mutation (SNP) | VAF 11/228 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.484); catalogued as COSV99924447; called by muse, mutect2
- TC2N | c.180T>A p.D60E | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100562793; called by muse, mutect2, varscan2
- TDO2 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.203); catalogued as COSV101539718; called by muse, mutect2
- TEAD3 | c.502C>G p.L168V | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.289); catalogued as COSV100132300; called by muse, mutect2, varscan2
- TET3 | c.1979C>T p.P660L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.127); catalogued as rs1273972145, COSV59880518; called by muse, mutect2, varscan2
- TFB1M | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 27/155 reads (17%) | catalogued as COSV100905149; called by muse, mutect2, varscan2
- TICRR | c.4255G>A p.D1419N | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.066); catalogued as COSV51549548; called by muse, mutect2, varscan2
- TRIB1 | c.424A>C p.N142H | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0.115); catalogued as COSV100322387; called by muse, mutect2, varscan2
- TRIP4 | c.1584C>G p.D528E | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.07); catalogued as COSV99974380; called by muse, mutect2
- TRPC1 | c.1540T>C p.F514L (on ENST00000476941 / NM_001251845.2; = p.F480L on NM_003304.4) | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as COSV99858337; called by muse, mutect2, varscan2
- TSHZ3 | c.2570G>A p.S857N | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV99550831; called by muse, mutect2
- TTC29 | c.633G>T p.L211F | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100283305, COSV57286747; called by muse, mutect2
- UPF1 | c.1417C>T p.R473C (on ENST00000599848 / NM_001297549.2; = p.R462C on NM_002911.4) | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV99438954; called by muse, mutect2, varscan2
- USH2A | c.8270A>G p.Y2757C | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs754257394, COSV100230432; called by muse, mutect2, varscan2
- USP40 | c.1191A>G p.I397M | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV99295900; called by muse, mutect2, varscan2
- VCPIP1 | c.1067T>G p.I356S | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV100125389, COSV60048685; called by muse, mutect2, varscan2
- VILL | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV52185913, COSV99378514; called by muse, mutect2, varscan2
- XIRP2 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 52/245 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.951); catalogued as rs553364503, COSV54711321, COSV54712210, COSV99737765; called by muse, mutect2, varscan2
- XKRX | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as COSV100139565; called by muse, mutect2
- YTHDF3 | c.1420T>G p.C474G | Missense Mutation (SNP) | VAF 17/287 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101572360; called by muse, mutect2
- ZFP36L1 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV100322505; called by muse, mutect2
- ZMYM3 | c.426G>T p.E142D | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV100077532; called by muse, mutect2, varscan2
- ZNF233 | c.1028G>A p.R343K | Missense Mutation (SNP) | VAF 12/280 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100492136; called by muse, mutect2
- ZNF280C | c.1323C>A p.N441K | Missense Mutation (SNP) | VAF 12/358 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV100921195; called by muse, mutect2
- ZNF678 | c.912G>C p.Q304H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.327); catalogued as COSV100652644; called by muse, mutect2, varscan2
- ZP3 | c.550G>A p.E184K (on ENST00000394857 / NM_001110354.2; = p.E133K on NM_007155.6) | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV100334469; called by muse, mutect2, varscan2
- ADAM21 | c.572_585del p.E191Gfs*7 | Frame Shift Del (DEL) | VAF 13/88 reads (15%) | called by mutect2, pindel, varscan2
- ARID4A | c.1950_1964del p.D650_D654del | In Frame Del (DEL) | VAF 27/230 reads (12%) | called by mutect2, pindel, varscan2
- DNER | c.342C>G p.S114R | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- MEGF11 | c.1673C>T p.T558I | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NCF2 | c.1291-1G>T p.X431_splice | Splice Site (SNP) | VAF 11/258 reads (4%) | called by muse, mutect2
- SYN3 | c.1592_1610+8del p.X531_splice | Splice Site (DEL) | VAF 25/155 reads (16%) | called by mutect2, pindel, varscan2
- USP12 | c.527_530del p.F176Wfs*4 | Frame Shift Del (DEL) | VAF 66/217 reads (30%) | called by mutect2, pindel, varscan2
- WDR47 | c.718_723del p.D241_L242del | In Frame Del (DEL) | VAF 27/93 reads (29%) | called by mutect2, pindel, varscan2
- WDR6 | c.1252_1280del p.K418Cfs*22 | Frame Shift Del (DEL) | VAF 19/58 reads (33%) | called by mutect2, pindel, varscan2
- ACTL7B | c.264C>T p.D88= | Silent (SNP) | VAF 39/50 reads (78%) | catalogued as rs1564198673, COSV65927243; called by muse, mutect2, varscan2
- C1orf159 | c.750C>G p.P250= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV99618225; called by muse, mutect2
- CACNA1E | c.5211G>T p.G1737= | Silent (SNP) | VAF 9/244 reads (4%) | catalogued as COSV100701410; called by muse, mutect2
- CMA1 | c.30C>A p.L10= | Silent (SNP) | VAF 27/153 reads (18%) | catalogued as COSV99157154; called by muse, mutect2, varscan2
- CRYGS | c.522C>A p.R174= | Silent (SNP) | VAF 33/95 reads (35%) | catalogued as COSV100329916; called by muse, mutect2, varscan2
- CSN3 | c.99T>C p.N33= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV100515273; called by muse, mutect2, varscan2
- CSPP1 | c.417C>T p.T139= (on ENST00000676605; = p.T98= on NM_024790.6) | Silent (SNP) | VAF 9/152 reads (6%) | catalogued as COSV99138084; called by muse, mutect2
- CUBN | c.9147A>T p.T3049= | Silent (SNP) | VAF 14/186 reads (8%) | catalogued as COSV100912189; called by muse, mutect2
- DNAJC17 | c.819C>T p.Y273= | Silent (SNP) | VAF 5/56 reads (9%) | catalogued as COSV99549050; called by muse, mutect2
- EYA1 | c.165G>A p.T55= | Silent (SNP) | VAF 22/332 reads (7%) | catalogued as rs745425275, COSV100378754; called by muse, mutect2
- FOXL2NB | c.498T>A p.A166= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV100374391; called by muse, mutect2, varscan2
- GLI3 | c.1377C>A p.T459= | Silent (SNP) | VAF 16/140 reads (11%) | catalogued as rs1005470831, COSV101229745; called by muse, mutect2, varscan2
- ITPR2 | c.6429C>A p.A2143= | Silent (SNP) | VAF 21/245 reads (9%) | catalogued as COSV101189854; called by muse, mutect2
- LAMA3 | c.2322A>C p.T774= | Silent (SNP) | VAF 16/162 reads (10%) | catalogued as COSV100555722; called by muse, mutect2, varscan2
- LIFR | c.2922C>T p.Y974= | Silent (SNP) | VAF 8/134 reads (6%) | catalogued as COSV99663474; called by muse, mutect2
- LIG1 | c.882G>A p.R294= | Silent (SNP) | VAF 17/223 reads (8%) | catalogued as COSV99618602; called by muse, mutect2
- LIN7C | c.18A>G p.E6= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV53415527; called by muse, mutect2, varscan2
- LRRC3 | c.478C>T p.L160= | Silent (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- MME | c.930T>C p.N310= | Silent (SNP) | VAF 38/140 reads (27%) | catalogued as COSV100852292; called by muse, mutect2, varscan2
- MSR1 | c.1329A>G p.E443= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV100026717; called by muse, mutect2
- PRSS36 | c.567C>A p.L189= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV51636891, COSV99191234; called by muse, mutect2, varscan2
- PTPRD | c.408G>A p.V136= | Silent (SNP) | VAF 106/205 reads (52%) | catalogued as rs1230875817, COSV100643763; called by muse, mutect2, varscan2
- RIPK2 | c.573C>T p.I191= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as rs200485473, COSV99609722; called by muse, mutect2, varscan2
- SETX | c.7257C>A p.L2419= | Silent (SNP) | VAF 23/270 reads (9%) | catalogued as COSV99808960; called by muse, mutect2
- SLC22A12 | c.678G>C p.A226= | Silent (SNP) | VAF 66/167 reads (40%) | catalogued as COSV100327426, COSV60572597; called by muse, varscan2
- SLC26A4 | c.1284T>C p.A428= | Silent (SNP) | VAF 39/173 reads (23%) | catalogued as CD982868, COSV99706641; called by muse, mutect2, varscan2
- SRC | c.870C>T p.N290= | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as rs1273222759, COSV100657985; called by muse, mutect2, varscan2
- SYNJ2 | c.1269T>C p.F423= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV100840056; called by muse, mutect2
- TTN | c.82707C>T p.F27569= (on ENST00000591111; = p.F20145= on NM_003319.4) | Silent (SNP) | VAF 43/157 reads (27%) | catalogued as COSV100598414; called by muse, mutect2, varscan2
- TYR | c.81T>A p.S27= | Silent (SNP) | VAF 54/156 reads (35%) | catalogued as COSV99633295; called by muse, mutect2, varscan2
- VCPIP1 | c.123C>T p.D41= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs201814170, COSV100125391; called by muse, mutect2, varscan2
- VIPR1 | c.105G>A p.E35= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV100285535; called by muse, mutect2, varscan2
- VN1R4 | c.300C>A p.L100= | Silent (SNP) | VAF 59/82 reads (72%) | catalogued as COSV100237340; called by muse, mutect2, varscan2
- XRCC5 | c.309A>G p.Q103= | Silent (SNP) | VAF 8/117 reads (7%) | catalogued as rs768296550, COSV67536406; called by muse, mutect2
- ZNF668 | c.1572C>G p.T524= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV100336433; called by muse, mutect2, varscan2
- HSPH1 | c.*1A>T | 3'UTR (SNP) | VAF 47/169 reads (28%) | catalogued as rs1244872387, COSV100184701; called by muse, mutect2, varscan2
- OPRM1 | c.1164+1875A>T | Intron (SNP) | VAF 51/127 reads (40%) | catalogued as rs780882968, COSV100000632; called by muse, mutect2, varscan2
- STK40 | c.-1A>C | 5'UTR (SNP) | VAF 35/142 reads (25%) | catalogued as COSV100828525; called by muse, mutect2, varscan2
